Somatic mutation profile of tumor specimen TCGA-RY-A83X-01A (aliquot TCGA-RY-A83X-01A-11D-A36O-08) from TCGA case TCGA-RY-A83X, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 46.3 years (16,911 days).
Specimen TCGA-RY-A83X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65c51788-9a91-4ee1-b0ae-afffd00d8b4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RY-A83X-10A (Blood Derived Normal), aliquot TCGA-RY-A83X-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abd80c11-2fc0-4f5d-afbc-87bbe14cb7e0

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 10, Silent 9, Nonsense Mutation 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 36/102 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA1 | c.5149G>A p.V1717I | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV101037046; called by muse, mutect2, varscan2
- ADAR | c.998T>G p.V333G | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV99426102; called by muse, mutect2, varscan2
- AGFG2 | c.1208T>C p.F403S | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.446); catalogued as COSV99499352; called by muse, mutect2, varscan2
- CCDC150 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as rs760076975, COSV55876633; called by muse, mutect2, varscan2
- DACH2 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100913329; called by muse, mutect2
- OR10Q1 | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.463); catalogued as rs376884240, COSV57472141; called by muse, mutect2, varscan2
- OR13D1 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs754928465, COSV100598691; called by muse, mutect2, varscan2
- PHF6 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 46/160 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV59706469; called by muse, mutect2, varscan2
- SORCS3 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV100865182; called by muse, mutect2
- SVIL | c.946G>C p.A316P | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.462); catalogued as COSV100880855, COSV100881289; called by muse, mutect2, varscan2
- ZNF638 | c.5695C>T p.R1899C | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754626232, COSV100038934; called by muse, mutect2, varscan2
- CIC | c.2171del p.G724Vfs*4 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | called by mutect2, pindel, varscan2
- ADCY4 | c.3006G>A p.P1002= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as rs757144908, COSV100156600; called by muse, mutect2
- EVPL | c.5079G>A p.T1693= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as rs757877898, COSV56907706, COSV56914013; called by muse, mutect2, varscan2
- FAM9C | c.192C>T p.T64= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV100452808; called by muse, mutect2
- IGF2BP3 | c.1113C>T p.N371= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs777472952, COSV99325452; called by muse, mutect2, varscan2
- LRIG3 | c.1707C>T p.R569= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs377193373; called by muse, mutect2, varscan2
- NEU2 | c.180C>T p.D60= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs138078170; called by muse, varscan2
- OR10H5 | c.360C>T p.Y120= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as rs772836837, COSV58277328; called by muse, mutect2, varscan2
- PKHD1L1 | c.11769G>A p.L3923= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV101006181; called by muse, mutect2, varscan2
- UBC | c.1107C>T p.S369= | Silent (SNP) | VAF 106/353 reads (30%) | catalogued as rs755797230, COSV100298996; called by muse, varscan2
